Somatic mutation profile of tumor specimen 0DQOF6 from CCDI case PBCFHZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.3 years (2,291 days).
Specimen 0DQOF6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41a3d77d-fe94-4a9e-b3ac-038afb09adc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQOEZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0355796d-060d-454f-894b-51ae661327ac

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZSCAN10 | c.905C>T p.P302L (on ENST00000252463; = p.P357L on NM_032805.3) | Missense Mutation (SNP) | VAF 165/358 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs367585417; called by muse, mutect2, varscan2
- MTOR | c.7114C>A p.P2372T | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDZD2 | c.3891G>A p.A1297= | Silent (SNP) | VAF 156/345 reads (45%) | catalogued as rs762003118, COSV99224492; called by muse, mutect2, varscan2
- STIM2 | c.1233C>T p.H411= | Silent (SNP) | VAF 202/499 reads (40%) | called by muse, mutect2, varscan2
- EXOC7 | c.1515+111C>T | Intron (SNP) | VAF 80/180 reads (44%) | catalogued as rs1377108779; called by muse, mutect2, varscan2
- PADI1 | c.1553-58T>G | Intron (SNP) | VAF 113/239 reads (47%) | called by muse, mutect2, varscan2
- PRSS8 | c.-9T>C | 5'UTR (SNP) | VAF 100/223 reads (45%) | called by muse, mutect2, varscan2
